Somatic mutation profile of tumor specimen CDDP-ACQA-TTP1-A (aliquot CDDP-ACQA-TTP1-A-1-0-D-A572-36) from CDDP_EAGLE case CDDP-ACQA, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 66 years.
Specimen CDDP-ACQA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06d46c0c-65f2-4f5a-9f0b-a892290c3860.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACQA-NB1-A (Blood Derived Normal), aliquot CDDP-ACQA-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93cff106-6a95-46fd-9eb5-f2befec0909f

The open-access MAF lists 534 somatic variants for this specimen: 331 protein-altering or splice-affecting, 118 silent, 85 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 288, Silent 118, Intron 38, Nonsense Mutation 20, 3'UTR 11, 5'UTR 10, RNA 10, 3'Flank 10, Frame Shift Del 7, Splice Region 7, 5'Flank 6, Splice Site 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 214/592 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.78C>A p.F26L | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV70043386; called by muse, mutect2, varscan2
- ABCA8 | c.3309+7A>G | Splice Region (SNP) | VAF 16/94 reads (17%) | catalogued as rs751434779; called by muse, mutect2, varscan2
- ABLIM2 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs925198356, COSV56406762; called by muse, mutect2, varscan2
- ACSM3 | c.250T>C p.W84R | Missense Mutation (SNP) | VAF 61/272 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55502283; called by muse, mutect2, varscan2
- ADGRF4 | c.1036A>G p.R346G | Missense Mutation (SNP) | VAF 67/249 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs753489113, COSV51953972; called by muse, mutect2, varscan2
- ADTRP | c.214G>T p.G72W | Missense Mutation (SNP) | VAF 71/375 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99995115; called by muse, mutect2, varscan2
- AFDN | c.3409C>G p.Q1137E | Missense Mutation (SNP) | VAF 69/463 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV60048201, COSV60050861; called by muse, mutect2, varscan2
- AHNAK | c.7483G>A p.D2495N | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as COSV57218891; called by muse, mutect2, varscan2
- AJM1 | c.1630G>T p.E544* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as COSV56033720; called by muse, mutect2, varscan2
- APOBEC3C | c.171C>A p.N57K | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV63865376, COSV63865614; called by muse, mutect2, varscan2
- ARGFX | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770818565, COSV100544207; called by muse, mutect2, varscan2
- ARHGAP45 | c.3016G>C p.E1006Q | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.127); catalogued as COSV53124512, COSV53125334; called by muse, mutect2, varscan2
- ARHGEF16 | c.923A>T p.E308V | Missense Mutation (SNP) | VAF 82/321 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV65682471; called by muse, mutect2, varscan2
- ARID4B | c.2794C>G p.Q932E | Missense Mutation (SNP) | VAF 48/430 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as COSV51611108; called by muse, mutect2, varscan2
- ATP13A3 | c.2738C>T p.S913F | Missense Mutation (SNP) | VAF 41/272 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55466490; called by muse, mutect2, varscan2
- BNC2 | c.2110G>C p.E704Q | Missense Mutation (SNP) | VAF 56/441 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV66141124, COSV66150880; called by muse, mutect2, varscan2
- BPIFB6 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.154); catalogued as COSV62755745; called by muse, mutect2
- BRCA1 | c.3071G>C p.S1024T | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as rs757579891, COSV58793428; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D3 | c.1577C>A p.A526E | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV55554000; called by muse, mutect2, varscan2
- CAPN14 | c.1549G>T p.E517* | Nonsense Mutation (SNP) | VAF 25/197 reads (13%) | catalogued as COSV67291125; called by muse, mutect2, varscan2
- CAPSL | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV68438473; called by muse, mutect2, varscan2
- CBLL2 | c.532A>G p.S178G | Missense Mutation (SNP) | VAF 58/92 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as COSV60369490; called by muse, mutect2, varscan2
- CCDC102B | c.1213C>G p.Q405E | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs1048430000, COSV60146119, COSV60156959; called by muse, varscan2
- CCDC9 | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs200888797; called by mutect2, varscan2
- CCNB3 | c.3949C>T p.L1317F | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52075662; called by muse, mutect2, varscan2
- CCNL1 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.49); catalogued as COSV55817212, COSV99904293; called by muse, mutect2, varscan2
- CCNYL1 | c.217G>C p.E73Q (on ENST00000295414 / NM_001330218.2; = p.E3Q on NM_152523.2) | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV54940652, COSV54940988; called by muse, mutect2, varscan2
- CCSER1 | c.2615C>T p.S872F | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61443123; called by muse, mutect2, varscan2
- CDH12 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 334/903 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs1428435649, COSV101202564, COSV66419690; called by muse, mutect2, varscan2
- CERKL | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59209811; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.1026G>C p.M342I | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as COSV55828831, COSV55829193; called by muse, mutect2, varscan2
- CFAP299 | c.152G>C p.R51P | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100812571, COSV63881323; called by muse, mutect2, varscan2
- CFAP74 | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 50/485 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.468); catalogued as rs780922875; called by muse, mutect2, varscan2
- CHST4 | c.909G>T p.Q303H | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV58297590; called by muse, mutect2, varscan2
- CLASP2 | c.4153G>A p.E1385K (on ENST00000359576; = p.E1384K on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs1006079166; called by muse, mutect2, varscan2
- CLSTN1 | c.2779G>A p.E927K (on ENST00000377298 / NM_001009566.3; = p.E917K on NM_014944.4) | Missense Mutation (SNP) | VAF 87/331 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.815); catalogued as rs1236274192, COSV63129705; called by mutect2, varscan2
- CLTCL1 | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54233688, COSV54239260; called by muse, mutect2, varscan2
- COL22A1 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1236773096, COSV57329333; called by mutect2, varscan2
- COPS4 | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs1038167837, COSV52315896; called by muse, mutect2
- CORO7 | c.2642C>T p.A881V | Missense Mutation (SNP) | VAF 74/254 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs369689601; called by muse, mutect2, varscan2
- CPO | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); catalogued as rs1218166720, COSV55940309; called by muse, mutect2, varscan2
- CRIM1 | c.2924C>T p.T975I | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs752295278; called by mutect2, varscan2
- CSN2 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 16/107 reads (15%) | catalogued as COSV61992355, COSV61992857; called by muse, mutect2, varscan2
- CTU1 | c.92G>T p.C31F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV70292536; called by muse, mutect2, varscan2
- CUL5 | c.822A>C p.K274N | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.318); catalogued as COSV67609342; called by muse, mutect2, varscan2
- CXCL16 | c.719A>G p.D240G | Missense Mutation (SNP) | VAF 87/256 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1402966715, COSV53411809; called by muse, mutect2, varscan2
- CXCR5 | c.442T>C p.Y148H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266536934, COSV52686266; called by muse, mutect2, varscan2
- CYHR1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV101446235; called by muse, mutect2
- DEPDC1 | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV63958650; called by muse, mutect2, varscan2
- DHRS3 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV66108434; called by muse, mutect2, varscan2
- DMD | c.875C>G p.P292R | Missense Mutation (SNP) | VAF 117/234 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs915965687, COSV55882396; called by muse, mutect2, varscan2
- DNAH9 | c.4565T>A p.L1522Q | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52358234; called by muse, mutect2, varscan2
- DNAJC6 | c.1234A>G p.I412V | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV54777455; called by muse, mutect2, varscan2
- DNASE1 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 78/547 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs758551072, COSV55913569; called by muse, varscan2
- DRC7 | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs1429861942, COSV61056088; called by muse, mutect2, varscan2
- EFNA3 | c.492C>G p.F164L | Missense Mutation (SNP) | VAF 64/348 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as COSV63625769; called by muse, mutect2, varscan2
- ENDOV | c.20G>C p.G7A | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV60498332; called by muse, mutect2, varscan2
- EPN1 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 154/451 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV50039658; called by muse, mutect2, varscan2
- EXOC6B | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); catalogued as COSV55560943; called by muse, mutect2, varscan2
- EXOSC3 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs767003713, COSV59203960; called by muse, mutect2, varscan2
- EYS | c.4040C>G p.S1347C | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV58200743; called by muse, mutect2, varscan2
- FAM135B | c.2419G>T p.G807C | Missense Mutation (SNP) | VAF 101/306 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as COSV52735537; called by muse, mutect2, varscan2
- FAT1 | c.13561C>T p.P4521S | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV71674866; called by muse, mutect2, varscan2
- FAT2 | c.1611C>G p.D537E | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55823283, COSV55825880; called by muse, mutect2, varscan2
- FBLN5 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 75/561 reads (13%) | catalogued as COSV99969367; called by muse, mutect2, varscan2
- FBN3 | c.3796C>T p.Q1266* | Nonsense Mutation (SNP) | VAF 48/273 reads (18%) | catalogued as COSV54464922; called by muse, mutect2, varscan2
- FBXO44 | c.369G>C p.K123N | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs761682227; called by muse, mutect2, varscan2
- FGF10 | c.297C>A p.S99R | Missense Mutation (SNP) | VAF 105/555 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.35); catalogued as rs759054084, COSV52933256, COSV52936198; called by muse, mutect2, varscan2
- FIGNL2 | c.997C>G p.L333V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV101626862; called by muse, mutect2, varscan2
- FLG2 | c.3121C>A p.H1041N | Missense Mutation (SNP) | VAF 217/868 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV66170054; called by muse, mutect2, varscan2
- FOXL2NB | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 77/357 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs865982825, COSV57728123; called by muse, mutect2, varscan2
- FRMPD4 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV66213075; called by muse, varscan2
- FRY | c.1615A>T p.S539C | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV66573153; called by muse, mutect2, varscan2
- GALNTL6 | c.1720G>C p.D574H | Missense Mutation (SNP) | VAF 89/445 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV72490060, COSV72491800; called by muse, mutect2, varscan2
- GDPD4 | c.1300T>C p.F434L | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV60020463; called by muse, mutect2, varscan2
- GFPT2 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 85/324 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV53809710; called by muse, mutect2, varscan2
- GLB1L3 | c.1397G>C p.R466P | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV68393070; called by muse, mutect2, varscan2
- GLRA1 | c.1202C>G p.P401R (on ENST00000455880 / NM_001146040.2; = p.P393R on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/318 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.826); catalogued as COSV51017329; called by muse, mutect2, varscan2
- GLUD2 | c.77C>G p.S26W | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100047136, COSV60152293; called by muse, mutect2, varscan2
- GOT1 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 105/320 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs769906176, COSV65147542; called by muse, mutect2, varscan2
- GPR107 | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61280721; called by muse, varscan2
- GPR107 | c.1076A>T p.K359M | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61280738; called by muse, varscan2
- GPR39 | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV61425015; called by muse, mutect2, varscan2
- GRIA1 | c.2057C>T p.T686I | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs749915140, COSV53610736; called by muse, mutect2, varscan2
- GRIA4 | c.319A>T p.T107S | Missense Mutation (SNP) | VAF 38/272 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.709); catalogued as COSV56905073; called by muse, mutect2, varscan2
- GRIA4 | c.1808T>C p.L603P | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV56905102; called by mutect2, varscan2
- GUCY1B1 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as COSV100025609, COSV52376734; called by mutect2, varscan2
- HDAC2 | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64038670; called by muse, mutect2, varscan2
- HERC2 | c.11402G>T p.G3801V | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV55332165; called by muse, mutect2, varscan2
- HIVEP3 | c.6057G>C p.R2019S | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV56018098; called by muse, mutect2, varscan2
- HPR | c.841T>A p.F281I | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57183504; called by muse, mutect2, varscan2
- IARS2 | c.2275A>T p.M759L | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.146); catalogued as COSV56961354; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 58/610 reads (10%) | catalogued as rs764934039; called by muse, mutect2
- IL17A | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as COSV100391544; called by muse, mutect2, varscan2
- INPPL1 | c.3250G>C p.E1084Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.047); catalogued as rs1311354993, COSV53355725, COSV53356922; called by mutect2, varscan2
- INTS1 | c.2551G>C p.D851H | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV67178203; called by muse, mutect2, varscan2
- ITGA8 | c.526C>G p.Q176E | Missense Mutation (SNP) | VAF 65/494 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as COSV65237350; called by muse, mutect2, varscan2
- KCNQ4 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 79/338 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61273927; called by muse, mutect2, varscan2
- KCNS3 | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 62/446 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV58407801; called by muse, mutect2, varscan2
- KCTD8 | c.134T>C p.V45A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV63591434; called by muse, mutect2, varscan2
- KDM4B | c.2615A>T p.E872V | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV50230939; called by mutect2, varscan2
- KIAA1549L | c.4537G>A p.E1513K (on ENST00000321505; = p.E1810K on NM_012194.3) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1318621265, COSV100381814; called by muse, varscan2
- KIAA1586 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV66056938; called by muse, mutect2, varscan2
- LCA5L | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV55746045; called by muse, mutect2, varscan2
- LEMD3 | c.54C>G p.F18L | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs377077013, COSV57648816; called by muse, mutect2, varscan2
- LINGO2 | c.1147G>T p.A383S | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0.012); catalogued as COSV58061219; called by muse, mutect2, varscan2
- LONRF2 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV66541243; called by muse, mutect2, varscan2
- LUZP1 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs372619729; called by muse, mutect2, varscan2
- LYPD2 | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 135/550 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as COSV63649611; called by muse, mutect2, varscan2
- MAGEE2 | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as COSV64898008; called by muse, mutect2, varscan2
- MAP3K8 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 116/503 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV53920487; called by muse, mutect2, varscan2
- MED23 | c.4068G>C p.Q1356H | Missense Mutation (SNP) | VAF 118/384 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.948); catalogued as COSV51581302; called by mutect2, varscan2
- MIPOL1 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 124/216 reads (57%) | catalogued as COSV59383013; called by muse, mutect2, varscan2
- MMEL1 | c.230G>C p.R77P | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs776455070; called by muse, mutect2, varscan2
- MPO | c.2142G>C p.K714N | Missense Mutation (SNP) | VAF 54/633 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.479); catalogued as COSV51860187; called by muse, mutect2
- MROH9 | c.2062G>A p.A688T | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1429738704, COSV63015058; called by muse, mutect2, varscan2
- MRPL9 | c.740G>C p.R247T | Missense Mutation (SNP) | VAF 83/424 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV58617467, COSV58618588; called by muse, varscan2
- MS4A14 | c.317T>C p.L106P | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV55736007; called by mutect2, varscan2
- MSH3 | c.1680G>T p.L560F | Missense Mutation (SNP) | VAF 74/297 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542448674; called by muse, mutect2, varscan2
- MSH4 | c.2275G>T p.D759Y | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54205763; called by muse, mutect2, varscan2
- MUC1 | c.3017C>G p.S1006C (on ENST00000611571 / NM_001371720.1; = p.S219C on NM_001204285.2) | Missense Mutation (SNP) | VAF 122/710 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1387726389, COSV58115984; called by muse, mutect2, varscan2
- MUC16 | c.13227G>T p.M4409I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV67476564; called by muse, mutect2, varscan2
- MUC20 | c.2036G>A p.R679K | Missense Mutation (SNP) | VAF 125/513 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as COSV57851894; called by muse, mutect2, varscan2
- MYH1 | c.4814T>C p.L1605P | Missense Mutation (SNP) | VAF 147/401 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56851625; called by muse, mutect2, varscan2
- MYOC | c.1073A>T p.K358M | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV50675858; called by muse, mutect2, varscan2
- NAALADL1 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770921192, COSV60524657; called by mutect2, varscan2
- NAGK | c.312C>G p.I104M | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.214); catalogued as COSV54903976; called by muse, mutect2, varscan2
- NAIP | c.187A>T p.R63W | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52001917; called by muse, mutect2, varscan2
- NEDD9 | c.221A>C p.H74P | Missense Mutation (SNP) | VAF 104/389 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV65159060; called by muse, mutect2, varscan2
- NLRP8 | c.1233G>C p.E411D | Missense Mutation (SNP) | VAF 76/286 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs781612277, COSV52587989, COSV52589954; called by muse, mutect2, varscan2
- NRIP1 | c.690G>C p.M230I | Missense Mutation (SNP) | VAF 56/369 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV59658509; called by muse, varscan2
- NRIP1 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV59658523; called by muse, mutect2, varscan2
- NRIP1 | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV59658530; called by muse, mutect2, varscan2
- NTRK2 | c.2444C>T p.P815L (on ENST00000323115 / NM_001369534.1; = p.P831L on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/422 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770827440, COSV52869629; called by muse, mutect2, varscan2
- NUMA1 | c.3560C>G p.S1187W | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs749408043, COSV61184030, COSV61187507; called by mutect2, varscan2
- NWD1 | c.4245G>A p.W1415* | Nonsense Mutation (SNP) | VAF 38/89 reads (43%) | catalogued as rs1469628602, COSV60342418; called by muse, mutect2
- OCA2 | c.747C>A p.H249Q | Missense Mutation (SNP) | VAF 138/383 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV62349935; called by muse, mutect2, varscan2
- OPLAH | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 114/356 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV70678498; called by muse, mutect2, varscan2
- OR10Q1 | c.582C>G p.C194W | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57470976; called by muse, mutect2, varscan2
- OR10W1 | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs1292305777, COSV67720180; called by muse, mutect2, varscan2
- OR4N2 | c.806A>T p.K269M | Missense Mutation (SNP) | VAF 133/441 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60052629, COSV60054547; called by muse, mutect2, varscan2
- OR5T2 | c.1033G>T p.G345W | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV57589859; called by muse, varscan2
- OR8K3 | c.424C>G p.Q142E | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.158); catalogued as COSV57132057; called by muse, mutect2, varscan2
- OTULINL | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 38/564 reads (7%) | catalogued as COSV57035120; called by muse, mutect2
- PGD | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs756735573, COSV54621455, COSV54622307; called by muse, mutect2, varscan2
- PIKFYVE | c.2937G>T p.L979F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.289); catalogued as COSV52244111; called by muse, mutect2, varscan2
- PIP4K2C | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.1); catalogued as COSV61606512; called by muse, mutect2, varscan2
- PKLR | c.1409C>A p.A470D | Missense Mutation (SNP) | VAF 252/1141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM061900, COSV61361713; called by muse, mutect2, varscan2
- PLXNA1 | c.3238C>G p.R1080G | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs777711019, COSV52528687, COSV99302521; called by muse, mutect2, varscan2
- PLXNA4 | c.112C>G p.R38G | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as COSV58138939; called by muse, mutect2, varscan2
- PMS2 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs886062400, COSV56222490; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POM121L12 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as rs763654322, COSV101374889, COSV68693349; called by muse, mutect2, varscan2
- POM121L2 | c.806C>A p.P269H | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.924); catalogued as COSV66276613; called by muse, mutect2, varscan2
- PRAG1 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.249); catalogued as rs371444632, COSV58163454; called by mutect2, varscan2
- PRAMEF18 | c.660G>A p.M220I | Missense Mutation (SNP) | VAF 36/476 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1312341836; called by muse, mutect2
- PRNP | c.680A>G p.Q227R | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV65173867; called by muse, mutect2, varscan2
- PTPRS | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as rs1303613614, COSV53616124; called by muse, mutect2, varscan2
- R3HDM1 | c.1699G>T p.A567S | Missense Mutation (SNP) | VAF 78/230 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV51527016; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV52863091; called by muse, mutect2, varscan2
- RASA3 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 28/474 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778354202, COSV61871780; called by muse, mutect2
- RASA3 | c.573T>G p.N191K | Missense Mutation (SNP) | VAF 58/278 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV61869229; called by muse, mutect2, varscan2
- RASGRF2 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 68/504 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54124625, COSV99429296; called by muse, mutect2, varscan2
- RERE | c.3536G>A p.R1179Q | Missense Mutation (SNP) | VAF 69/557 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.837); catalogued as rs150925051; called by muse, mutect2, varscan2
- RUNDC3A | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV56588049; called by muse, mutect2, varscan2
- RUNX1T1 | c.1139G>C p.R380P (on ENST00000265814 / NM_001198628.1; = p.R353P on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 231/801 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56152543; called by muse, mutect2, varscan2
- RYR3 | c.3334G>T p.V1112F | Missense Mutation (SNP) | VAF 107/283 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.215); catalogued as COSV66797563; called by muse, mutect2, varscan2
- SAFB | c.281A>C p.K94T | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52652264; called by muse, mutect2, varscan2
- SCARF2 | c.1406G>A p.G469D | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs1472497655, COSV56732951; called by muse, mutect2, varscan2
- SCN1A | c.5664G>C p.Q1888H (on ENST00000303395 / NM_001202435.3; = p.Q1877H on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV57666973, COSV57676226; called by muse, mutect2, varscan2
- SDCCAG8 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 53/415 reads (13%) | catalogued as COSV59412148; called by muse, mutect2, varscan2
- SGCZ | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as rs751791396, COSV66023617; called by muse, mutect2, varscan2
- SHMT1 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 213/584 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57399456; called by muse, mutect2, varscan2
- SLC18B1 | c.897+1G>A p.X299_splice | Splice Site (SNP) | VAF 45/232 reads (19%) | catalogued as COSV99259024; called by muse, mutect2, varscan2
- SLC39A11 | c.623-1G>C p.X208_splice (on ENST00000542342 / NM_001159770.2; = p.X201_splice on NM_139177.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 39/246 reads (16%) | catalogued as COSV99723264; called by muse, mutect2, varscan2
- SLC39A12 | c.1855A>T p.I619F (on ENST00000377369 / NM_001145195.2; = p.I582F on NM_152725.3) | Missense Mutation (SNP) | VAF 110/465 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV66199929; called by muse, mutect2, varscan2
- SLC6A3 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 36/634 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs2617604; called by muse, mutect2
- SMAD1 | c.613C>A p.H205N | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV57471921, COSV57473542; called by muse, mutect2, varscan2
- SMG9 | c.898G>T p.V300F | Missense Mutation (SNP) | VAF 103/303 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV54215244; called by muse, mutect2, varscan2
- SP1 | c.740C>A p.S247* (on ENST00000327443 / NM_138473.3; = p.S240* on NM_003109.1) | Nonsense Mutation (SNP) | VAF 54/172 reads (31%) | catalogued as COSV100540411, COSV59403851; called by muse, varscan2
- SP1 | c.938C>T p.S313L (on ENST00000327443 / NM_138473.3; = p.S306L on NM_003109.1) | Missense Mutation (SNP) | VAF 137/417 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs749256985, COSV59403875; called by muse, mutect2, varscan2
- SPACA3 | c.274C>G p.R92G | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52191660; called by muse, mutect2, varscan2
- SPRY1 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (0.945); catalogued as COSV59337986; called by muse, mutect2
- SQLE | c.728C>G p.A243G | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV56281592; called by muse, mutect2, varscan2
- SRCAP | c.9035A>T p.K3012M | Missense Mutation (SNP) | VAF 55/304 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV52675642; called by muse, mutect2, varscan2
- SRL | c.822G>C p.W274C | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV68423757; called by muse, mutect2, varscan2
- SSTR3 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60729751; called by muse, mutect2, varscan2
- STX11 | c.761A>C p.D254A | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.144); catalogued as COSV62448422; called by muse, mutect2, varscan2
- STYXL2 | c.3021C>G p.F1007L | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV54802548, COSV54806305; called by muse, mutect2, varscan2
- SULF1 | c.1225G>C p.D409H | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.538); catalogued as COSV52685689; called by muse, mutect2, varscan2
- SYNPO2 | c.3224C>T p.S1075L | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs758183161, COSV61113437; called by muse, mutect2, varscan2
- TAFA2 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV69181945; called by muse, mutect2, varscan2
- TATDN1 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 83/311 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV52677893, COSV52680556; called by muse, mutect2, varscan2
- TBC1D22A | c.1466G>T p.W489L | Missense Mutation (SNP) | VAF 58/359 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61441383; called by muse, mutect2, varscan2
- TCHH | c.4018G>A p.E1340K | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.299); catalogued as rs771735914, COSV64272995; called by muse, mutect2, varscan2
- TDRD5 | c.1549G>C p.D517H | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1386447818, COSV54245361; called by muse, mutect2, varscan2
- TEX15 | c.6045A>T p.L2015F (on ENST00000256246; = p.L2398F on NM_001350162.2) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV56348688; called by muse, varscan2
- TFAP2A | c.655C>T p.R219C (on ENST00000482890; = p.R211C on NM_001032280.3) | Missense Mutation (SNP) | VAF 67/528 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as CM110098, CM151475; called by muse, mutect2, varscan2
- THAP7 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs755408769, COSV53145783, COSV99301459; called by mutect2, varscan2
- TLR3 | c.2155A>G p.I719V | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV57169291; called by muse, mutect2, varscan2
- TMC2 | c.1781C>A p.T594K | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753558671, COSV62651145, COSV62654986; called by muse, mutect2, varscan2
- TMC8 | c.1352T>G p.L451R | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV59210366; called by muse, mutect2, varscan2
- TOE1 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 109/378 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.035); catalogued as COSV59154158; called by muse, mutect2, varscan2
- TPH2 | c.1341C>G p.F447L | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV61592711; called by muse, mutect2, varscan2
- TRIM27 | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101019518; called by muse, mutect2
- TRIM45 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 91/335 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV56713692, COSV56714109; called by muse, mutect2, varscan2
- TRIM66 | c.1113A>C p.K371N | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55127017; called by muse, mutect2, varscan2
- TRIP12 | c.47C>A p.S16* | Nonsense Mutation (SNP) | VAF 64/326 reads (20%) | catalogued as COSV52267098; called by muse, mutect2, varscan2
- TRIP13 | c.490G>T p.V164F | Missense Mutation (SNP) | VAF 112/762 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51320514; called by muse, mutect2, varscan2
- TROAP | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV57743355; called by muse, mutect2, varscan2
- TRPA1 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 42/476 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV51557317; called by muse, mutect2
- TTN | c.13985A>G p.E4662G (on ENST00000591111; = p.E3735G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | PolyPhen probably damaging (0.997); catalogued as COSV60163650; called by muse, mutect2, varscan2
- TUBA3C | c.752A>C p.D251A | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV67139563; called by muse, mutect2, varscan2
- UAP1 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as rs773513701, COSV54851667; called by muse, mutect2
- UBR1 | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV51932303; called by muse, mutect2, varscan2
- VCX3B | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs368402392, COSV66842494; called by muse, varscan2
- WDFY4 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 93/242 reads (38%) | catalogued as COSV57439860; called by muse, mutect2, varscan2
- WFIKKN2 | c.895G>C p.D299H | Missense Mutation (SNP) | VAF 100/298 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.2); catalogued as COSV60959262; called by muse, mutect2, varscan2
- WWC1 | c.2128A>G p.T710A | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54653718; called by muse, varscan2
- XPO7 | c.1156C>G p.R386G | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53016713; called by muse, mutect2, varscan2
- YME1L1 | c.778A>G p.I260V (on ENST00000326799 / NM_139312.3; = p.I203V on NM_014263.4) | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs1276758171, COSV58760285; called by muse, mutect2, varscan2
- ZFHX4 | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.028); catalogued as COSV50520822; called by muse, mutect2, varscan2
- ZKSCAN5 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 116/282 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV58743351; called by muse, mutect2, varscan2
- ZNF256 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 74/217 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV56598248; called by muse, mutect2, varscan2
- ZNF415 | c.675G>C p.L225F | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54702704; called by muse, mutect2, varscan2
- ZNF423 | c.1149C>A p.S383R (on ENST00000563137 / NM_001379286.1; = p.S375R on NM_015069.4) | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as COSV52195156; called by muse, mutect2, varscan2
- ZNF446 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52180007, COSV52181335; called by muse, mutect2, varscan2
- ZNF473 | c.2527C>G p.Q843E | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.682); catalogued as COSV54523460; called by muse, mutect2
- ZNF521 | c.3325G>A p.V1109I | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1259251891, COSV64129625; called by muse, mutect2, varscan2
- ZNF527 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 114/386 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV62231903; called by muse, mutect2, varscan2
- ZRANB2 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.899); catalogued as COSV54671960; called by muse, mutect2, varscan2
- ZSCAN12 | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 28/215 reads (13%) | catalogued as COSV63011055; called by muse, varscan2
- ZSCAN12 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 68/420 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV63011065; called by muse, varscan2
- ZSCAN12 | c.1047G>C p.Q349H | Missense Mutation (SNP) | VAF 78/438 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV63011070; called by muse, mutect2, varscan2
- ZSCAN12 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV63011075; called by muse, varscan2
- ADAMTS9 | c.4180-1G>T p.X1394_splice | Splice Site (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- AHRR | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 67/532 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANGEL2 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 66/458 reads (14%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ARHGEF28 | c.2998_2999del p.T1000Sfs*22 | Frame Shift Del (DEL) | VAF 28/165 reads (17%) | called by mutect2, pindel, varscan2
- ARPP21 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BTNL8 | c.406T>A p.S136T | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- BUB3 | c.1-1G>A p.X1_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- C4orf45 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 43/317 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- CARF | c.1531G>C p.E511Q | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- CARMIL3 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CCDC168 | c.12653G>C p.R4218T | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.161); called by muse, mutect2
- CCT8L2 | c.1470G>C p.Q490H | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CECR2 | c.2648T>C p.F883S (on ENST00000342247 / NM_001290047.2; = p.F700S on NM_001290046.1) | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CECR2 | c.4243G>A p.E1415K (on ENST00000342247 / NM_001290047.2; = p.E1231K on NM_001290046.1) | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- CEP135 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CHD5 | c.3068C>G p.S1023* | Nonsense Mutation (SNP) | VAF 32/327 reads (10%) | called by muse, mutect2
- CHL1 | c.1775C>T p.S592L (on ENST00000397491 / NM_001253387.1; = p.S608L on NM_006614.4) | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLTRN | c.174G>C p.M58I | Missense Mutation (SNP) | VAF 77/171 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CNGB1 | c.1643+3G>T | Splice Region (SNP) | VAF 26/131 reads (20%) | called by muse, mutect2, varscan2
- CNNM4 | c.795C>G p.I265M | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- CYP11B1 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 276/946 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CYP4A11 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 33/219 reads (15%) | called by muse, mutect2, varscan2
- ECT2L | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 40/438 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EPAS1 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- FAM160A1 | c.3079C>G p.L1027V | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM90A1 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 25/175 reads (14%) | called by muse, mutect2, varscan2
- FBXO22 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- FCSK | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- FYCO1 | c.1819G>C p.E607Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.062); called by muse, varscan2
- GAD2 | c.448del p.A150Qfs*11 | Frame Shift Del (DEL) | VAF 43/246 reads (17%) | called by mutect2, pindel, varscan2
- GRIA2 | c.1340_1342dup p.V447dup | In Frame Ins (INS) | VAF 80/341 reads (23%) | called by mutect2, pindel, varscan2
- HMX1 | c.396C>A p.T132= | Splice Region (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- IMPACT | c.774G>C p.K258N | Missense Mutation (SNP) | VAF 92/293 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- IQGAP2 | c.4195G>C p.E1399Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.155); called by muse, mutect2
- IZUMO4 | c.555-1G>A p.X185_splice | Splice Site (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- JMY | c.1403C>A p.A468E | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, varscan2
- KDM4C | c.1678-1G>A p.X560_splice | Splice Site (SNP) | VAF 100/343 reads (29%) | called by muse, mutect2, varscan2
- LSP1 | c.185A>C p.E62A | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by mutect2, varscan2
- MAPK1 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 33/351 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- METRN | c.565+8T>C | Splice Region (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2, varscan2
- MMEL1 | c.1239G>C p.Q413H | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MRC2 | c.872G>C p.G291A | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MS4A18 | c.757T>C p.S253P (on ENST00000398983; = p.S255P on NM_001354471.1) | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- MYCBP2 | c.5481G>C p.L1827F (on ENST00000357337; = p.L1865F on NM_015057.5) | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH7 | c.3327G>C p.K1109N | Missense Mutation (SNP) | VAF 56/460 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCOA6 | c.2446C>T p.Q816* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | called by mutect2, varscan2
- NGDN | c.367+7G>A | Splice Region (SNP) | VAF 28/243 reads (12%) | called by muse, mutect2, varscan2
- OPA1 | c.2937G>C p.K979N (on ENST00000361510 / NM_130837.3; = p.K924N on NM_015560.3) | Missense Mutation (SNP) | VAF 60/425 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PARP8 | c.1172del p.G391Efs*11 | Frame Shift Del (DEL) | VAF 32/137 reads (23%) | called by mutect2, pindel, varscan2
- PCDHA4 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCDHA7 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 102/754 reads (14%) | called by muse, mutect2, varscan2
- PCDHGC4 | c.440_451del p.P147_Q150del | In Frame Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel
- PDZD2 | c.8320G>C p.D2774H | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- PER3 | c.1015C>A p.P339T | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PI4KA | c.5452G>C p.E1818Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); called by mutect2, varscan2
- PIK3CA | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 39/330 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PKD1L1 | c.1839G>T p.W613C | Missense Mutation (SNP) | VAF 56/491 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- PKP1 | c.1230G>C p.L410F | Missense Mutation (SNP) | VAF 49/415 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.06); called by mutect2, varscan2
- POLA1 | c.1374+7C>G | Splice Region (SNP) | VAF 32/61 reads (52%) | called by muse, mutect2, varscan2
- PPP1R35 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2
- PRPSAP1 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- PSKH1 | c.957+3G>C | Splice Region (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- PSMB9 | c.164C>G p.S55C | Missense Mutation (SNP) | VAF 74/191 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- PSMD8 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRZ1 | c.4282G>T p.D1428Y | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.96); called by mutect2, varscan2
- RAD51D | c.265C>G p.L89V | Missense Mutation (SNP) | VAF 151/607 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- RASGRF2 | c.62A>C p.K21T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, varscan2
- ROS1 | c.415C>A p.L139M | Missense Mutation (SNP) | VAF 51/524 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2
- RP1 | c.2953G>A p.A985T | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- RTF1 | c.838C>G p.Q280E | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SDE2 | c.1322del p.L441Yfs*6 | Frame Shift Del (DEL) | VAF 64/440 reads (15%) | called by mutect2, pindel, varscan2
- SESN1 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC5A12 | c.1277T>A p.L426Q | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SMG1 | c.1150G>T p.V384L | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA22 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPTA1 | c.5233C>G p.L1745V | Missense Mutation (SNP) | VAF 169/674 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SYNPO | c.2206G>C p.E736Q (on ENST00000394243 / NM_001166208.2; = p.E492Q on NM_007286.6) | Missense Mutation (SNP) | VAF 107/865 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- SZT2 | c.3822C>G p.H1274Q (on ENST00000634258 / NM_001365999.1; = p.H1217Q on NM_015284.4) | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF4B | c.2024A>C p.E675A | Missense Mutation (SNP) | VAF 34/295 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- TENM3 | c.2234del p.G745Vfs*31 | Frame Shift Del (DEL) | VAF 54/205 reads (26%) | called by mutect2, pindel, varscan2
- TFAP2D | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- THOC1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- TNS3 | c.440A>C p.K147T | Missense Mutation (SNP) | VAF 34/372 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRIM5 | c.353del p.E118Gfs*23 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- TRMT1L | c.337_338insA p.L113Hfs*2 | Frame Shift Ins (INS) | VAF 24/127 reads (19%) | called by mutect2, pindel, varscan2
- UQCRC1 | c.793C>G p.L265V | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP41 | c.697T>A p.C233S | Missense Mutation (SNP) | VAF 58/399 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XRRA1 | c.287_291del p.H96Lfs*12 | Frame Shift Del (DEL) | VAF 17/153 reads (11%) | called by mutect2, pindel, varscan2
- ZBTB8A | c.1203G>C p.L401F | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- ZC3HAV1L | c.332A>C p.H111P | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- ZKSCAN2 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZMYM4 | c.347G>C p.R116T | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF146 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- ZNF208 | c.2608T>C p.Y870H | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ZNF573 | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ZNF75A | c.762C>G p.F254L | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- ABCA7 | c.2310G>C p.R770= | Silent (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- ADAD1 | c.450T>C p.S150= | Silent (SNP) | VAF 26/214 reads (12%) | catalogued as COSV56644782; called by muse, mutect2, varscan2
- ADAM11 | c.726G>A p.E242= | Silent (SNP) | VAF 82/311 reads (26%) | catalogued as rs555358248, COSV52347463; called by muse, mutect2, varscan2
- ADAMTS12 | c.1260C>A p.S420= | Silent (SNP) | VAF 160/514 reads (31%) | catalogued as rs1401148978, COSV61267657; called by muse, mutect2, varscan2
- AMER3 | c.156C>A p.G52= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV58467915; called by muse, mutect2, varscan2
- ANKLE2 | c.2337C>T p.P779= | Silent (SNP) | VAF 84/242 reads (35%) | catalogued as rs200992817, COSV61710242; called by muse, mutect2, varscan2
- APC | c.6414G>C p.L2138= | Silent (SNP) | VAF 33/235 reads (14%) | catalogued as COSV57356359; called by muse, mutect2, varscan2
- ASB11 | c.405C>T p.L135= | Silent (SNP) | VAF 41/87 reads (47%) | catalogued as COSV60354846, COSV60355672; called by muse, mutect2, varscan2
- ATG16L2 | c.687C>A p.A229= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV58361379; called by muse, mutect2, varscan2
- ATP8B2 | c.828C>T p.F276= (on ENST00000672630; = p.F243= on NM_001005855.2) | Silent (SNP) | VAF 34/315 reads (11%) | catalogued as rs201913757, COSV59249807; called by muse, mutect2, varscan2
- C5orf52 | c.15T>C p.T5= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV69626148; called by muse, mutect2, varscan2
- CACNA2D2 | c.2511G>A p.L837= (on ENST00000479441 / NM_001174051.3; = p.L830= on NM_006030.4) | Silent (SNP) | VAF 39/213 reads (18%) | catalogued as COSV56565201; called by muse, mutect2, varscan2
- CAPN10 | c.435G>T p.V145= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as COSV54377503; called by muse, varscan2
- CARD10 | c.2823C>T p.V941= | Silent (SNP) | VAF 46/409 reads (11%) | catalogued as rs1042786525; called by muse, mutect2, varscan2
- CBLN2 | c.414G>T p.P138= | Silent (SNP) | VAF 34/170 reads (20%) | catalogued as COSV54050642, COSV54051822; called by muse, mutect2, varscan2
- CDH9 | c.1957C>A p.R653= | Silent (SNP) | VAF 42/566 reads (7%) | catalogued as COSV50320975, COSV99142080; called by muse, mutect2
- CIITA | c.1962C>A p.P654= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as rs769190445, COSV60854939, COSV60859158, COSV60859574; called by muse, mutect2, varscan2
- CMYA5 | c.1515G>A p.E505= | Silent (SNP) | VAF 28/194 reads (14%) | catalogued as rs754035398; called by muse, mutect2, varscan2
- CRP | c.651C>T p.F217= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV54813993; called by muse, mutect2, varscan2
- CTC1 | c.1926C>A p.L642= | Silent (SNP) | VAF 63/289 reads (22%) | catalogued as COSV100236733; called by muse, mutect2, varscan2
- DAND5 | c.456C>T p.R152= | Silent (SNP) | VAF 122/349 reads (35%) | catalogued as rs776471948, COSV57684334; called by muse, mutect2, varscan2
- DCAF8L2 | c.945C>A p.A315= | Silent (SNP) | VAF 81/169 reads (48%) | catalogued as COSV70551163; called by muse, mutect2, varscan2
- DCST1 | c.1044C>T p.L348= | Silent (SNP) | VAF 38/484 reads (8%) | catalogued as COSV99793628; called by muse, mutect2
- DDX24 | c.2364G>A p.L788= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs1472385973, COSV52572990; called by mutect2, varscan2
- DLG5 | c.4092C>T p.I1364= | Silent (SNP) | VAF 91/198 reads (46%) | catalogued as rs1402006813, COSV64948121, COSV64949902; called by muse, mutect2, varscan2
- DNAJA3 | c.876C>T p.C292= | Silent (SNP) | VAF 43/380 reads (11%) | called by muse, mutect2, varscan2
- DUT | c.189G>C p.L63= | Silent (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- DYNC1LI2 | c.783C>T p.F261= | Silent (SNP) | VAF 43/214 reads (20%) | called by muse, mutect2, varscan2
- DZIP1L | c.699G>T p.R233= | Silent (SNP) | VAF 72/309 reads (23%) | catalogued as COSV59521998; called by muse, mutect2, varscan2
- ENPP3 | c.1281C>T p.L427= | Silent (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- ETS1 | c.159C>T p.F53= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as COSV60098100; called by muse, mutect2, varscan2
- F5 | c.3843C>T p.S1281= | Silent (SNP) | VAF 143/619 reads (23%) | catalogued as COSV63125572; called by muse, mutect2, varscan2
- FAM83H | c.1662G>A p.A554= | Silent (SNP) | VAF 43/244 reads (18%) | catalogued as rs1390924637, COSV66354877; called by muse, mutect2, varscan2
- FAT3 | c.12966G>T p.V4322= | Silent (SNP) | VAF 30/208 reads (14%) | catalogued as COSV53134422; called by muse, mutect2, varscan2
- FOXP4 | c.24G>A p.E8= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV57221116; called by muse, mutect2, varscan2
- FYCO1 | c.1758G>A p.G586= | Silent (SNP) | VAF 12/73 reads (16%) | called by muse, varscan2
- GBX2 | c.576G>A p.P192= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs757987864, COSV60444902; called by muse, mutect2, varscan2
- GGT5 | c.1095C>A p.I365= | Silent (SNP) | VAF 49/173 reads (28%) | catalogued as COSV54072736; called by muse, mutect2, varscan2
- GIMAP1 | c.495C>T p.Y165= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV56188838; called by muse, mutect2, varscan2
- H2BC18 | c.60G>T p.T20= | Silent (SNP) | VAF 107/614 reads (17%) | catalogued as COSV100516183, COSV58944534; called by muse, mutect2, varscan2
- H4C5 | c.213G>A p.V71= | Silent (SNP) | VAF 19/163 reads (12%) | catalogued as rs779424083, COSV63486292; called by muse, mutect2, varscan2
- HERC6 | c.1591C>T p.L531= | Silent (SNP) | VAF 147/485 reads (30%) | catalogued as COSV52031726; called by muse, mutect2, varscan2
- HEYL | c.132G>A p.R44= | Silent (SNP) | VAF 21/163 reads (13%) | called by muse, mutect2, varscan2
- ITGB2 | c.801C>T p.F267= | Silent (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
- ITIH5 | c.591C>T p.I197= | Silent (SNP) | VAF 76/292 reads (26%) | catalogued as rs369114884, COSV56904119, COSV56912641; called by muse, mutect2, varscan2
- KCNB2 | c.1878C>A p.A626= | Silent (SNP) | VAF 74/396 reads (19%) | catalogued as COSV73051162; called by muse, mutect2, varscan2
- KIF13B | c.5193C>T p.V1731= | Silent (SNP) | VAF 56/361 reads (16%) | catalogued as rs368165412; called by muse, mutect2, varscan2
- KIF3B | c.237A>G p.P79= | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as rs1569200373, COSV65228209; called by muse, mutect2, varscan2
- KIF7 | c.2277G>A p.L759= | Silent (SNP) | VAF 33/190 reads (17%) | catalogued as rs1245465021; called by muse, mutect2, varscan2
- KRT24 | c.942G>A p.L314= | Silent (SNP) | VAF 38/322 reads (12%) | called by muse, mutect2, varscan2
- KRT26 | c.768G>A p.L256= | Silent (SNP) | VAF 59/549 reads (11%) | called by muse, mutect2, varscan2
- KRT71 | c.321C>G p.V107= | Silent (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- LDLRAD3 | c.75C>T p.F25= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs753990428; called by mutect2, varscan2
- LMNTD1 | c.150G>A p.L50= | Silent (SNP) | VAF 78/236 reads (33%) | catalogued as COSV51448385; called by muse, mutect2, varscan2
- LUZP2 | c.30G>T p.L10= | Silent (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- MROH6 | c.589C>T p.L197= | Silent (SNP) | VAF 21/335 reads (6%) | catalogued as rs960450424; called by muse, mutect2
- MS4A14 | c.360T>C p.V120= | Silent (SNP) | VAF 58/244 reads (24%) | catalogued as COSV55736017; called by muse, mutect2, varscan2
- MUC15 | c.234C>A p.P78= | Silent (SNP) | VAF 67/183 reads (37%) | catalogued as rs985596895, COSV55555502; called by muse, mutect2, varscan2
- MYPN | c.2370A>G p.T790= | Silent (SNP) | VAF 65/188 reads (35%) | catalogued as COSV62735317; called by muse, mutect2, varscan2
- NCAPD3 | c.2847C>T p.L949= | Silent (SNP) | VAF 31/260 reads (12%) | catalogued as rs150304737; called by muse, mutect2, varscan2
- NCDN | c.1341C>T p.I447= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as COSV61936130; called by muse, mutect2, varscan2
- NCOA6 | c.2121C>G p.L707= | Silent (SNP) | VAF 21/165 reads (13%) | catalogued as rs746581581; called by muse, mutect2, varscan2
- NEK11 | c.1605G>T p.L535= | Silent (SNP) | VAF 176/380 reads (46%) | catalogued as COSV67281199; called by muse, mutect2, varscan2
- NKX6-2 | c.228G>A p.L76= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs902759547, COSV63973987; called by muse, mutect2, varscan2
- NRIP1 | c.927G>A p.Q309= | Silent (SNP) | VAF 29/170 reads (17%) | catalogued as COSV59658500; called by muse, mutect2, varscan2
- NRIP1 | c.618G>C p.V206= | Silent (SNP) | VAF 46/254 reads (18%) | catalogued as COSV59658517; called by muse, varscan2
- OR2T1 | c.144C>A p.I48= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as COSV100822247, COSV63542330; called by muse, mutect2, varscan2
- OR5T1 | c.663C>T p.V221= | Silent (SNP) | VAF 74/274 reads (27%) | catalogued as COSV100478843, COSV57303452, COSV57304714; called by muse, mutect2, varscan2
- P2RX6 | c.126G>A p.Q42= | Silent (SNP) | VAF 38/326 reads (12%) | called by muse, mutect2, varscan2
- PAK4 | c.490A>C p.R164= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV58945628; called by muse, mutect2, varscan2
- PAPPA2 | c.2568C>G p.T856= | Silent (SNP) | VAF 49/182 reads (27%) | catalogued as COSV62779636, COSV62780953; called by muse, mutect2, varscan2
- PAQR7 | c.135G>T p.P45= | Silent (SNP) | VAF 30/254 reads (12%) | catalogued as COSV65351927; called by muse, varscan2
- PCDHA1 | c.2118G>A p.A706= | Silent (SNP) | VAF 46/376 reads (12%) | catalogued as rs1487786462, COSV65374515; called by muse, mutect2, varscan2
- PCED1A | c.558C>T p.L186= | Silent (SNP) | VAF 38/185 reads (21%) | catalogued as rs374829387; called by muse, mutect2, varscan2
- PHF12 | c.693G>C p.L231= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99256329; called by muse, mutect2
- PIK3CG | c.174G>C p.L58= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV63249236, COSV63250013; called by muse, mutect2, varscan2
- PKHD1 | c.7284C>T p.D2428= | Silent (SNP) | VAF 39/318 reads (12%) | catalogued as rs200807210, COSV61883250; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- PKLR | c.891C>G p.V297= | Silent (SNP) | VAF 52/550 reads (9%) | catalogued as rs1409005837, COSV61362135; called by muse, mutect2
- PLEKHG1 | c.2058A>T p.S686= | Silent (SNP) | VAF 38/118 reads (32%) | catalogued as COSV62048635; called by muse, mutect2, varscan2
- POLG | c.384G>T p.P128= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as rs558958919, COSV51522878; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRR19 | c.228C>T p.L76= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as COSV56626095; called by muse, mutect2, varscan2
- PTK2 | c.1308A>G p.V436= | Silent (SNP) | VAF 81/238 reads (34%) | catalogued as COSV61785108; called by muse, mutect2, varscan2
- RAPGEF5 | c.538C>T p.L180= (on ENST00000401957 / NM_001367602.2; = p.L483= on NM_012294.5) | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV59786538; called by muse, mutect2, varscan2
- REG3G | c.246G>T p.G82= | Silent (SNP) | VAF 100/321 reads (31%) | catalogued as COSV55450314; called by muse, mutect2, varscan2
- RHAG | c.396C>A p.V132= | Silent (SNP) | VAF 114/465 reads (25%) | catalogued as COSV57705147; called by muse, mutect2, varscan2
- RIMS1 | c.3534C>A p.G1178= | Silent (SNP) | VAF 71/272 reads (26%) | catalogued as COSV53465306; called by muse, mutect2, varscan2
- SCARF2 | c.1347G>T p.L449= | Silent (SNP) | VAF 57/421 reads (14%) | catalogued as COSV56732962; called by mutect2, varscan2
- SGCZ | c.93T>A p.T31= | Silent (SNP) | VAF 34/135 reads (25%) | catalogued as COSV66023620; called by muse, mutect2, varscan2
- SIGMAR1 | c.399C>T p.F133= | Silent (SNP) | VAF 160/534 reads (30%) | catalogued as COSV52844788; called by muse, mutect2, varscan2
- SLC10A6 | c.987C>T p.V329= | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as rs62305601, COSV56722179; called by muse, mutect2, varscan2
- SOCS7 | c.1893G>A p.A631= | Silent (SNP) | VAF 14/170 reads (8%) | catalogued as rs138060923; called by muse, mutect2
- SOST | c.255C>T p.F85= | Silent (SNP) | VAF 26/288 reads (9%) | called by muse, mutect2
- SP1 | c.807C>G p.V269= (on ENST00000327443 / NM_138473.3; = p.V262= on NM_003109.1) | Silent (SNP) | VAF 110/377 reads (29%) | catalogued as COSV59403866; called by muse, varscan2
- SPP2 | c.603G>T p.R201= | Silent (SNP) | VAF 118/332 reads (36%) | catalogued as COSV51445897; called by muse, mutect2, varscan2
- SRD5A1 | c.123C>T p.H41= | Silent (SNP) | VAF 17/288 reads (6%) | called by muse, mutect2
- SSBP4 | c.72C>T p.Y24= | Silent (SNP) | VAF 75/201 reads (37%) | catalogued as rs377735423; called by muse, mutect2, varscan2
- STXBP5L | c.582C>A p.I194= | Silent (SNP) | VAF 55/201 reads (27%) | catalogued as COSV56520546; called by muse, mutect2, varscan2
- SUGT1 | c.345T>C p.H115= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as rs1194835141; called by mutect2, varscan2
- SUSD4 | c.972G>A p.A324= | Silent (SNP) | VAF 27/172 reads (16%) | catalogued as rs1374887211; called by muse, mutect2, varscan2
- SYT11 | c.207C>G p.L69= | Silent (SNP) | VAF 119/666 reads (18%) | catalogued as COSV64175172, COSV64176124; called by muse, mutect2, varscan2
- TAF4 | c.1654C>T p.L552= | Silent (SNP) | VAF 35/209 reads (17%) | catalogued as COSV53339412; called by muse, mutect2, varscan2
- TEX14 | c.1776G>C p.L592= (on ENST00000240361 / NM_001201457.2; = p.L586= on NM_031272.5) | Silent (SNP) | VAF 53/418 reads (13%) | called by muse, mutect2, varscan2
- TEX26 | c.869G>A p.*290= | Silent (SNP) | VAF 21/106 reads (20%) | called by muse, mutect2, varscan2
- TLE2 | c.2231G>A p.*744= | Silent (SNP) | VAF 12/82 reads (15%) | called by muse, varscan2
- TLR4 | c.2445G>C p.L815= (on ENST00000355622 / NM_138554.5; = p.L775= on NM_003266.4) | Silent (SNP) | VAF 135/435 reads (31%) | catalogued as COSV62923669; called by muse, mutect2, varscan2
- TMEM67 | c.762G>A p.V254= | Silent (SNP) | VAF 36/380 reads (9%) | called by muse, mutect2
- TOPBP1 | c.33G>A p.V11= | Silent (SNP) | VAF 18/178 reads (10%) | catalogued as COSV53437905; called by muse, mutect2
- TOX | c.1153C>T p.L385= | Silent (SNP) | VAF 119/359 reads (33%) | catalogued as rs773880622, COSV63266503; called by muse, mutect2, varscan2
- TRIO | c.6789C>T p.I2263= | Silent (SNP) | VAF 24/440 reads (5%) | called by muse, mutect2
- TTN | c.2193C>A p.T731= (on ENST00000591111; = p.T685= on NM_003319.4) | Silent (SNP) | VAF 98/341 reads (29%) | catalogued as COSV60163660; called by muse, mutect2, varscan2
- TUBA4A | c.1143G>C p.T381= | Silent (SNP) | VAF 22/139 reads (16%) | called by muse, mutect2, varscan2
- TYW1 | c.621G>C p.V207= | Silent (SNP) | VAF 24/134 reads (18%) | called by muse, mutect2, varscan2
- USP18 | c.762C>T p.I254= | Silent (SNP) | VAF 42/420 reads (10%) | called by muse, mutect2, varscan2
- VHL | c.42C>T p.G14= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV56554175; called by muse, mutect2, varscan2
- VWF | c.7032C>G p.L2344= | Silent (SNP) | VAF 65/477 reads (14%) | called by muse, mutect2, varscan2
- ZAN | c.4338A>G p.G1446= | Silent (SNP) | VAF 106/385 reads (28%) | called by muse, mutect2, varscan2
- ZNF75A | c.54C>G p.L18= | Silent (SNP) | VAF 22/294 reads (7%) | called by muse, mutect2
- ZSCAN12 | c.1299G>A p.Q433= | Silent (SNP) | VAF 26/219 reads (12%) | catalogued as COSV63011061; called by muse, varscan2
- ABR | c.532-28C>T | Intron (SNP) | VAF 125/329 reads (38%) | catalogued as rs769115328; called by muse, mutect2, varscan2
- AC112695.1 | n.256A>G | RNA (SNP) | VAF 15/128 reads (12%) | called by muse, mutect2, varscan2
- AC243919.1 | n.324C>T | RNA (SNP) | VAF 117/360 reads (33%) | called by muse, mutect2, varscan2
- ADCYAP1 | c.-78C>G | 5'UTR (SNP) | VAF 15/204 reads (7%) | called by muse, mutect2
- AL109984.1 | n.186+1118C>G | Intron (SNP) | VAF 56/226 reads (25%) | catalogued as COSV63753105; called by muse, mutect2, varscan2
- AL138759.1 | n.208-2799A>G | Intron (SNP) | VAF 17/166 reads (10%) | catalogued as rs1413802823; called by muse, varscan2
- ANKRD52 | c.-6C>G | 5'UTR (SNP) | VAF 34/151 reads (23%) | called by muse, mutect2, varscan2
- APTX | c.181-30A>G | Intron (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- ATP11AUN | n.980G>A | RNA (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- BPNT1 | c.*1048A>G | 3'UTR (SNP) | VAF 12/100 reads (12%) | called by muse, varscan2
- C15orf40 | chr15:82991972 C>G | 3'Flank (SNP) | VAF 34/197 reads (17%) | called by muse, varscan2
- C19orf12 | chr19:29699524 C>A | 3'Flank (SNP) | VAF 83/477 reads (17%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29700080 C>G | 3'Flank (SNP) | VAF 53/355 reads (15%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29700887 C>G | 3'Flank (SNP) | VAF 100/399 reads (25%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29702321 C>T | 3'Flank (SNP) | VAF 186/712 reads (26%) | called by muse, mutect2, varscan2
- CD1E | c.-16C>A | 5'UTR (SNP) | VAF 41/126 reads (33%) | catalogued as COSV100937020, COSV63770007; called by muse, mutect2, varscan2
- CD22 | chr19:35329170 C>A | 5'Flank (SNP) | VAF 85/478 reads (18%) | called by muse, mutect2, varscan2
- CFAP74 | c.2176+528T>C | Intron (SNP) | VAF 42/291 reads (14%) | catalogued as rs1269130496; called by muse, mutect2, varscan2
- CHODL | c.*41C>G | 3'UTR (SNP) | VAF 31/297 reads (10%) | catalogued as COSV53042648; called by muse, varscan2
- CLSTN3 | c.64+1120del | Intron (DEL) | VAF 96/382 reads (25%) | called by mutect2, pindel, varscan2
- CNOT2 | c.49-13063A>G | Intron (SNP) | VAF 16/108 reads (15%) | called by muse, varscan2
- CORO1B | c.757-338C>T | Intron (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- CPAMD8 | c.5567+129G>A | Intron (SNP) | VAF 27/175 reads (15%) | catalogued as rs994902243; called by muse, varscan2
- CSNK1G2 | c.-266+12481G>A | Intron (SNP) | VAF 52/141 reads (37%) | called by muse, mutect2, varscan2
- CYB5RL | c.541-743T>C | Intron (SNP) | VAF 10/97 reads (10%) | called by mutect2, varscan2
- CYP2D7 | c.986-34C>T | Intron (SNP) | VAF 10/65 reads (15%) | catalogued as rs1470574386; called by muse, mutect2, varscan2
- CYS1 | chr2:10085165 G>A | 5'Flank (SNP) | VAF 37/374 reads (10%) | catalogued as rs775943227; called by muse, mutect2, varscan2
- CYYR1 | c.-107C>T | 5'UTR (SNP) | VAF 34/91 reads (37%) | catalogued as rs1236587558; called by muse, mutect2, varscan2
- DPY19L2P2 | n.3977G>T | RNA (SNP) | VAF 53/178 reads (30%) | called by muse, mutect2, varscan2
- EGFL7 | c.571+307C>A | Intron (SNP) | VAF 41/175 reads (23%) | called by muse, mutect2, varscan2
- ERFE | c.887+12C>A | Intron (SNP) | VAF 68/239 reads (28%) | called by muse, mutect2, varscan2
- FAM136A | c.87+376G>T | Intron (SNP) | VAF 83/298 reads (28%) | called by muse, mutect2, varscan2
- FAM151B | chr5:80488070 C>G | 5'Flank (SNP) | VAF 16/122 reads (13%) | catalogued as rs755094522, COSV56471628; called by mutect2, varscan2
- FAM227A | c.*3204C>G | 3'UTR (SNP) | VAF 52/344 reads (15%) | called by muse, varscan2
- FANCM | c.5341-631C>G | Intron (SNP) | VAF 30/286 reads (10%) | called by muse, mutect2, varscan2
- FAP | c.1402+472G>A | Intron (SNP) | VAF 55/192 reads (29%) | catalogued as rs1404587466; called by muse, mutect2, varscan2
- FILIP1L | c.605+25528T>C | Intron (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2
- GON4L | c.5631+75C>G | Intron (SNP) | VAF 36/396 reads (9%) | called by muse, mutect2
- IFT43 | c.368+40G>T | Intron (SNP) | VAF 61/147 reads (41%) | called by muse, varscan2
- JMJD6 | chr17:76716695 A>T | 3'Flank (SNP) | VAF 102/222 reads (46%) | catalogued as COSV58301805; called by muse, mutect2, varscan2
- JPH4 | c.1151+84G>T | Intron (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- KDM2A | c.308-11082C>T | Intron (SNP) | VAF 22/158 reads (14%) | catalogued as rs1565398839; called by muse, mutect2, varscan2
- KIFC1 | c.250+2087A>T | Intron (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- LDHA | chr11:18407859 A>G | 3'Flank (SNP) | VAF 47/131 reads (36%) | called by muse, mutect2, varscan2
- LEFTY2 | c.251-29G>T | Intron (SNP) | VAF 39/266 reads (15%) | called by muse, mutect2, varscan2
- MACF1 | c.220+18378C>T | Intron (SNP) | VAF 36/348 reads (10%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1124-88C>A | Intron (SNP) | VAF 115/236 reads (49%) | catalogued as COSV100025460, COSV68923879; called by muse, mutect2, varscan2
- MARCHF1 | c.242+853C>A | Intron (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- MAZ | c.*190C>T | 3'UTR (SNP) | VAF 86/401 reads (21%) | catalogued as rs1169867296; called by muse, mutect2, varscan2
- MBD3 | c.*2898A>G | 3'UTR (SNP) | VAF 8/68 reads (12%) | called by mutect2, varscan2
- METTL26 | c.197+30G>A | Intron (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- MIDEAS | c.*350G>A | 3'UTR (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- MIF4GD | chr17:75272315 G>A | 5'Flank (SNP) | VAF 22/191 reads (12%) | called by muse, mutect2, varscan2
- MXD4 | c.165-935G>T | Intron (SNP) | VAF 22/147 reads (15%) | catalogued as rs1460249471; called by muse, mutect2, varscan2
- NDEL1 | c.-109G>C | 5'UTR (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- NELFA | c.416-607G>T | Intron (SNP) | VAF 51/180 reads (28%) | catalogued as rs774731001; called by muse, mutect2, varscan2
- NLE1 | c.1214+306G>A | Intron (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.747G>T | RNA (SNP) | VAF 69/234 reads (29%) | catalogued as rs1240432367; called by muse, mutect2, varscan2
- OGN | chr9:92404579 G>A | 5'Flank (SNP) | VAF 24/192 reads (13%) | called by muse, mutect2, varscan2
- PCSK6 | chr15:101300812 G>C | 3'Flank (SNP) | VAF 22/124 reads (18%) | called by muse, varscan2
- PI4KAP2 | n.2928G>C | RNA (SNP) | VAF 48/506 reads (9%) | called by muse, mutect2
- PRPF3 | c.1641-42G>A | Intron (SNP) | VAF 93/341 reads (27%) | catalogued as rs782397839; called by muse, mutect2, varscan2
- PSTPIP1 | c.37-10277A>G | Intron (SNP) | VAF 20/228 reads (9%) | catalogued as rs1433736046, COSV51200834; called by muse, mutect2
- RAB2A | c.-14G>C | 5'UTR (SNP) | VAF 16/135 reads (12%) | called by muse, mutect2, varscan2
- REV3L | c.9043-618T>A | Intron (SNP) | VAF 14/86 reads (16%) | catalogued as rs1356395055; called by muse, mutect2
- RGL1 | c.-15G>C | 5'UTR (SNP) | VAF 14/234 reads (6%) | called by muse, mutect2
- ROBO2 | c.3935-1957C>T | Intron (SNP) | VAF 148/357 reads (41%) | catalogued as rs761095553; called by muse, mutect2, varscan2
- SASH3 | c.-12G>C | 5'UTR (SNP) | VAF 51/85 reads (60%) | called by muse, mutect2, varscan2
- SCOC-AS1 | n.268G>C | RNA (SNP) | VAF 33/171 reads (19%) | called by muse, mutect2, varscan2
- SDHA | c.-10A>G | 5'UTR (SNP) | VAF 34/100 reads (34%) | catalogued as rs3211464; called by muse, mutect2, varscan2
- SLC12A5 | c.*3A>T | 3'UTR (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- SLC35E3 | c.*1975C>A | 3'UTR (SNP) | VAF 5/63 reads (8%) | catalogued as rs1421284515; called by mutect2, varscan2
- SMAD6 | c.952+812G>A | Intron (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- SMARCB1 | chr22:23834505 C>G | 3'Flank (SNP) | VAF 28/174 reads (16%) | called by muse, mutect2, varscan2
- SOBP | c.-25C>G | 5'UTR (SNP) | VAF 76/334 reads (23%) | called by muse, mutect2, varscan2
- SSPOP | n.4295C>A | RNA (SNP) | VAF 77/199 reads (39%) | catalogued as COSV50488112; called by muse, mutect2, varscan2
- SSPOP | n.4296C>A | RNA (SNP) | VAF 78/202 reads (39%) | catalogued as COSV50488119; called by muse, mutect2, varscan2
- STAG3L2 | n.1023G>T | RNA (SNP) | VAF 46/405 reads (11%) | catalogued as rs1554426472; called by muse, mutect2
- STUB1 | chr16:684413 C>T | 3'Flank (SNP) | VAF 20/245 reads (8%) | called by muse, mutect2
- STX4 | c.133-16C>T | Intron (SNP) | VAF 21/144 reads (15%) | catalogued as rs1335783742, COSV58268745; called by muse, mutect2, varscan2
- TRIM74 | chr7:72969948 C>T | 5'Flank (SNP) | VAF 29/387 reads (7%) | catalogued as rs1233413370; called by muse, mutect2, varscan2
- UMPS | c.*377A>C | 3'UTR (SNP) | VAF 17/229 reads (7%) | catalogued as rs927558442; called by muse, mutect2
- UQCRB | c.*867G>C | 3'UTR (SNP) | VAF 12/113 reads (11%) | catalogued as rs1246472599; called by muse, mutect2
- UVSSA | c.*9526C>T | 3'UTR (SNP) | VAF 188/687 reads (27%) | catalogued as COSV61347533; called by muse, varscan2
- YTHDF2 | c.27+15C>T | Intron (SNP) | VAF 19/155 reads (12%) | catalogued as rs1224164247; called by muse, mutect2, varscan2
